Somatic mutation profile of tumor specimen BLGSP-71-08-00040-01A (aliquot BLGSP-71-08-00040-01A-01D-A663-33) from CGCI case BLGSP-71-08-00040, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male; Vital status: Alive; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 7.4 years (2,687 days).
Specimen BLGSP-71-08-00040-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Spleen; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d12ffea0-cd63-4b2c-ac7f-3061dbfa39b3.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BLGSP-71-08-00040-10A (Blood Derived Normal), aliquot BLGSP-71-08-00040-10A-01D-A663-33; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/992c6d6f-18e9-4290-8470-126b0df4b03a

The open-access MAF lists 12 somatic variants for this specimen: 4 protein-altering or splice-affecting, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 3, 5'UTR 3, Missense Mutation 2, 5'Flank 2, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.517G>A p.V173M | Missense Mutation (SNP) | VAF 45/49 reads (92%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs876660754, CM070299, COSV52676535, COSV52677795, COSV52695723, COSV52823354; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- DDX3X | c.441-1G>A p.X147_splice (on ENST00000399959; = p.X148_splice on NM_001356.5) | Splice Site (SNP) | VAF 227/255 reads (89%) | catalogued as COSV67863411; called by muse, mutect2, varscan2
- AC072022.2 | c.82A>T p.N28Y | Missense Mutation (SNP) | VAF 90/208 reads (43%) | called by muse, mutect2, varscan2
- FBXO11 | c.503_505del p.F168del (on ENST00000403359 / NM_001190274.2; = p.F84del on NM_025133.4 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 200/385 reads (52%) | called by pindel, varscan2
- AC072022.2 | c.-63T>G | 5'UTR (SNP) | VAF 24/68 reads (35%) | catalogued as COSV69207524; called by muse, varscan2
- AC072022.2 | c.-14del | 5'UTR (DEL) | VAF 32/106 reads (30%) | called by pindel, varscan2
- BACH2 | c.-446+960A>C | Intron (SNP) | VAF 13/37 reads (35%) | called by muse, mutect2, varscan2
- CXCR4 | c.15+399C>T | Intron (SNP) | VAF 101/237 reads (43%) | called by muse, mutect2, varscan2
- EBF1 | chr5:159100759 C>G | 5'Flank (SNP) | VAF 4/13 reads (31%) | called by muse, mutect2, varscan2
- FOXP1 | c.-298+625G>A | Intron (SNP) | VAF 201/402 reads (50%) | called by muse, mutect2, varscan2
- MYC | c.-461A>C | 5'UTR (SNP) | VAF 18/30 reads (60%) | called by muse, mutect2
- TSPOAP1 | chr17:58331915 C>T | 5'Flank (SNP) | VAF 118/230 reads (51%) | called by muse, mutect2, varscan2
